Surgical pathology report (de-identified scan), TCGA case TCGA-TT-A6YJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pennsylvania, specimen TCGA-TT-A6YJ-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Accession No:

Physician:

Copy to:

Surgical Pathology Report

Accession Number Collection Date/Time Received Date/Time Verified Date/Time Pathologist

Clinical Information

Left adrenal pheochromocytoma
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Laparoscopic adrenal
Specific questions to be answered: None.

Specimen:

1 Left Adrenal Mass

Final Diagnosis

1. Adrenal gland, left, adrenalectomy:
Adrenal pheochromocytoma, 3.0 cm, see note.

The case material was reviewed and the report verified

(Electronic signature)

Note

There is no evidence of increased mitotic activity, vascular invasion, necrosis, or profound nuclear pleomorphism. The PASS score is 0.

Gross Description

The specimen is received fresh in one container labeled with the patient's name and medical record number and designated "left adrenal mass". It consists of an adrenal gland weighing 23.9 g and measuring overall 5.8 x 4.3 x 2.8 cm. There is a rounded mass within the specimen measuring 3 x 2.8 x 2.6 cm. There is a staple line on one end measuring 2.5 cm in length. The entire specimen is inked in black. The specimen is sectioned to reveal a pale, well circumscribed, yellow-tan, hemorrhagic, soft mass. The mass is friable in the center. A portion from the center is given to tumor bank. The staple line is shaved and submitted as 1A. The mass in relation to adrenal is submitted in cassettes 1B-1G. Uninvolved adrenal gland submitted as 1H.

Name:
MRN:

[page 2 of 2]
Sex: Female

Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Summary of sections: 8, 8, representative

Pathologist(s)

Name:
MRN:

Source: NCI Genomic Data Commons file 515685c1-7187-468b-858a-98fd0de3b3bd (TCGA-TT-A6YJ.1743037E-E653-489C-9EBF-C9343B63B375.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).